Somatic mutation profile of tumor specimen 0DMLA3 from CCDI case PBCARC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Thorax, NOS; Age at diagnosis: 16.1 years (5,882 days).
Specimen 0DMLA3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d260ce6-04cd-4d34-9e7c-78753b997b18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DML9O (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f26cb715-0300-44f2-9028-8cdf2ee33dd2

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Intron 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 361/944 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CAMTA1 | c.1303G>A p.V435M | Missense Mutation (SNP) | VAF 180/392 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.084); catalogued as rs145233171; called by muse, mutect2, varscan2
- EBAG9 | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 640/1554 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs746651770; called by muse, varscan2
- OR6C6 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 274/1067 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs757658611, COSV64456046; called by muse, mutect2, varscan2
- VPS13A | c.1360C>G p.L454V | Missense Mutation (SNP) | VAF 255/827 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.195); catalogued as COSV100652915; called by muse, mutect2, varscan2
- TSSK6 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 234/649 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ARHGAP36 | c.1317C>T p.R439= | Silent (SNP) | VAF 318/772 reads (41%) | catalogued as rs189514802, COSV52264345; called by muse, mutect2, varscan2
- CLEC18B | c.921C>T p.D307= | Silent (SNP) | VAF 153/1831 reads (8%) | catalogued as rs372921914; called by muse, varscan2
- FLRT1 | c.642G>A p.P214= | Silent (SNP) | VAF 246/585 reads (42%) | catalogued as rs769538146; called by muse, mutect2, varscan2
- C9orf62 | n.652G>T | RNA (SNP) | VAF 57/149 reads (38%) | called by muse, mutect2, varscan2
- ME2 | c.393-86T>A | Intron (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- MROH1 | c.4775-23C>T | Intron (SNP) | VAF 260/536 reads (49%) | catalogued as rs1244017548; called by muse, varscan2
